Somatic mutation profile of tumor specimen TCGA-18-3415-01A (aliquot TCGA-18-3415-01A-01D-0983-08) from TCGA case TCGA-18-3415, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.8 years (28,430 days).
Specimen TCGA-18-3415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29a37fb8-5d55-42bd-9380-a5cb548ec5b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3415-11A (Solid Tissue Normal), aliquot TCGA-18-3415-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3d5b742-38c1-4b89-9caf-5e3c346e20fa

The open-access MAF lists 188 somatic variants for this specimen: 142 protein-altering or splice-affecting, 41 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 41, Nonsense Mutation 11, In Frame Del 3, Splice Site 3, 5'Flank 2, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- TP53 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5801A>T p.Q1934L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV70032454; called by muse, mutect2, varscan2
- ABCD2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58052500; called by muse, mutect2, varscan2
- ACAP2 | c.1011-2A>T p.X337_splice | Splice Site (SNP) | VAF 81/173 reads (47%) | catalogued as COSV58752835; called by muse, mutect2, varscan2
- ACER2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs770384271, COSV61820954; called by muse, mutect2, varscan2
- ADAM22 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs375078730; called by mutect2, varscan2
- ADAMTS12 | c.4580A>T p.N1527I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV61266177; called by muse, mutect2, varscan2
- AGPAT2 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760141111, COSV58247674; called by muse, varscan2
- AHCTF1 | c.3823C>T p.P1275S (on ENST00000366508; = p.P1249S on NM_015446.5) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58251583; called by muse, mutect2, varscan2
- AHI1 | c.1793C>A p.P598Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99662402; called by muse, mutect2, varscan2
- ALG13 | c.2136G>T p.E712D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV52640491; called by muse, mutect2, varscan2
- BTN3A3 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs144256388; called by mutect2, varscan2
- C1QL3 | c.410A>T p.H137L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV54348920; called by muse, mutect2
- C2CD5 | c.2413A>T p.T805S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV61725335; called by muse, mutect2, varscan2
- C2orf78 | c.1469G>T p.C490F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV68518037; called by muse, mutect2, varscan2
- C7orf31 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV52218373; called by muse, mutect2, varscan2
- CADPS2 | c.3548G>C p.R1183P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57368717; called by muse, mutect2, varscan2
- CCBE1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761881641, COSV67950286, COSV67951393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC81 | c.1423G>C p.D475H (on ENST00000445632 / NM_001156474.2; = p.D385H on NM_021827.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53579324; called by muse, mutect2, varscan2
- CCDC87 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV59579439; called by muse, varscan2
- CDK5RAP3 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58115315; called by muse, mutect2, varscan2
- CFAP54 | c.6313C>T p.Q2105* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV61572798; called by muse, mutect2, varscan2
- CFTR | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs76727851, CM003244, COSV50063373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.3019C>T p.L1007F | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV71112116; called by muse, mutect2, varscan2
- COPB1 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV51448998; called by muse, mutect2, varscan2
- CPS1 | c.3620C>A p.T1207N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51813773; called by muse, mutect2, varscan2
- CSMD1 | c.2315C>A p.P772H (on ENST00000520002; = p.P771H on NM_033225.6) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59338394; called by muse, mutect2, varscan2
- DBH | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs527742213, COSV55041466; called by muse, mutect2, varscan2
- DENND2A | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs562738531, COSV52053144; called by muse, mutect2, varscan2
- DHX57 | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV54886661; called by muse, mutect2, varscan2
- DNAH7 | c.4840G>A p.G1614R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56770023; called by muse, mutect2
- DOCK7 | c.4417G>A p.G1473R (on ENST00000635253 / NM_001367561.1; = p.G1442R on NM_033407.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52010121; called by muse, mutect2, varscan2
- DYNC1H1 | c.3016-1G>C p.X1006_splice | Splice Site (SNP) | VAF 42/146 reads (29%) | catalogued as COSV64138209; called by muse, varscan2
- DYNC1H1 | c.3142G>C p.E1048Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64138215; called by muse, varscan2
- FAM3B | c.500C>G p.A167G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV63613358; called by muse, mutect2, varscan2
- FANCM | c.6000G>T p.M2000I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57502458, COSV57507235; called by muse, mutect2, varscan2
- FLG | c.5048C>T p.S1683F | Missense Mutation (SNP) | VAF 257/573 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs754927316, COSV64243251; called by muse, mutect2, varscan2
- FLRT1 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1372497918, COSV99734994; called by muse, mutect2
- FPGT | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV63841931; called by muse, mutect2, varscan2
- FSIP2 | c.16234C>A p.P5412T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV100554708; called by muse, mutect2, varscan2
- FSIP2 | c.17536G>C p.V5846L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV100554714; called by muse, mutect2, varscan2
- GLDC | c.2623A>T p.N875Y | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV58681289; called by muse, mutect2, varscan2
- GPR161 | c.859A>G p.M287V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV54791619; called by muse, mutect2, varscan2
- GPR87 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV53462145, COSV53464367; called by muse, mutect2, varscan2
- GRIK3 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66136268; called by muse, mutect2, varscan2
- H3C2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- HDAC5 | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV56819706; called by muse, mutect2, varscan2
- HELB | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758231002, COSV56074237; called by muse, mutect2, varscan2
- ITPRID1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV60076359; called by muse, mutect2, varscan2
- KIF23 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV52980631; called by muse, mutect2, varscan2
- KIR2DL3 | c.394T>G p.S132A | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV60898301; called by muse, mutect2, varscan2
- KLHL1 | c.1113T>A p.D371E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV64774777; called by muse, mutect2, varscan2
- LEPR | c.3341G>A p.R1114K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV62748989; called by muse, mutect2, varscan2
- LMBRD2 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56950784; called by muse, mutect2, varscan2
- LRCH1 | c.1353G>C p.M451I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV60848860; called by muse, mutect2, varscan2
- LRG1 | c.44T>C p.I15T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56704361; called by muse, mutect2, varscan2
- LRP1B | c.6729C>A p.Y2243* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV67236084, COSV67277916; called by muse, mutect2, varscan2
- MB21D2 | c.1113C>A p.N371K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.046); catalogued as COSV66664136; called by mutect2, varscan2
- MS4A14 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV55735669; called by muse, mutect2, varscan2
- MUC16 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV67474308; called by muse, mutect2, varscan2
- NALCN | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as COSV51943412; called by muse, mutect2, varscan2
- NARF | c.869A>G p.H290R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1248173872, COSV59112276; called by muse, mutect2, varscan2
- NCOA2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 36/238 reads (15%) | catalogued as COSV71764211, COSV71765023; called by muse, mutect2, varscan2
- NDST4 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52124089, COSV99996753; called by muse, mutect2, varscan2
- NEUROG2 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57637011, COSV57637532; called by muse, mutect2, varscan2
- NGLY1 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV54987469; called by muse, mutect2, varscan2
- NNT | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.226); catalogued as COSV52926060; called by muse, mutect2, varscan2
- NOL11 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV53523974; called by muse, mutect2, varscan2
- NOS1 | c.3599T>G p.V1200G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57614910; called by muse, mutect2, varscan2
- OR2L3 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV100742071, COSV63455473; called by muse, varscan2
- OR4C3 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs769715475, COSV60587142; called by muse, mutect2, varscan2
- OR4K13 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV59859335, COSV59859895; called by muse, mutect2, varscan2
- OR52R1 | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61888729; called by muse, mutect2, varscan2
- OR8H3 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV57909656; called by muse, mutect2, varscan2
- OR9A2 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV63306765; called by muse, mutect2, varscan2
- OSBPL10 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.109); catalogued as rs1365774128, COSV67340636; called by muse, mutect2, varscan2
- PDE12 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV60818799; called by muse, mutect2, varscan2
- PDE4B | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58472670, COSV58482267; called by muse, mutect2, varscan2
- PELI2 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50712060; called by muse, mutect2, varscan2
- PHAX | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV52551522; called by muse, mutect2, varscan2
- PHF19 | c.615-1G>A p.X205_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56489992; called by muse, mutect2, varscan2
- PHF3 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV50322600; called by muse, mutect2, varscan2
- PLRG1 | c.1409T>C p.F470S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57423852; called by muse, mutect2, varscan2
- RELL1 | c.778G>C p.A260P | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.48); catalogued as COSV58450396, COSV58452382; called by muse, mutect2, varscan2
- RIMBP2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.795); catalogued as COSV55475850; called by muse, mutect2, varscan2
- RNASEH2B | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs575985863, COSV60746792; called by muse, mutect2, varscan2
- RPL10L | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs895630945, COSV53560268; called by muse, mutect2, varscan2
- RPL13 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs140485395; called by muse, mutect2, varscan2
- RTN4 | c.1588G>C p.V530L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV58269119; called by muse, mutect2, varscan2
- RYR2 | c.4445G>C p.R1482P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV63692093; called by muse, mutect2, varscan2
- RYR2 | c.4751C>T p.P1584L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs772098320, COSV63682006, COSV63692099; called by muse, mutect2
- S100PBP | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV65110781; called by muse, mutect2, varscan2
- SCN2A | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM163734, COSV51845479; called by muse, mutect2, varscan2
- SEC13 | c.520C>T p.Q174* (on ENST00000350697 / NM_183352.3; = p.Q177* on NM_030673.4) | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as COSV61601892; called by muse, mutect2, varscan2
- SETD4 | c.1255A>T p.T419S | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as COSV59772590; called by muse, mutect2, varscan2
- SH3RF2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV63039620; called by muse, mutect2, varscan2
- SLC13A1 | c.1716G>A p.W572* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as rs1410166299, COSV52013068; called by muse, mutect2, varscan2
- SLC14A2 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54910327, COSV99675194; called by muse, mutect2, varscan2
- SLC20A1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs760040356, COSV55611769, COSV55612392, COSV99733981; called by muse, mutect2, varscan2
- SLC24A2 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV53867440; called by muse, mutect2, varscan2
- SLC26A7 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs1157926782, COSV52596124; called by muse, mutect2, varscan2
- SLC7A13 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs749418698, COSV52533236; called by muse, mutect2, varscan2
- SOCS2 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV61392265; called by muse, mutect2
- SOWAHB | c.2174C>A p.A725D | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV57554714; called by muse, mutect2, varscan2
- SPATA31E1 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as rs1564127831, COSV57792141, COSV57792761; called by muse, mutect2, varscan2
- SPTBN2 | c.4748G>A p.R1583Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs972140635, COSV59448812; called by muse, mutect2, varscan2
- SRBD1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV55400486; called by muse, mutect2, varscan2
- STK17B | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55828768; called by muse, mutect2, varscan2
- STXBP5L | c.2637G>T p.E879D | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV56518627; called by muse, mutect2, varscan2
- TMEM144 | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56701530; called by muse, mutect2, varscan2
- TRAK1 | c.90T>A p.C30* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59643961; called by muse, mutect2, varscan2
- TRIM3 | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61984298; called by muse, mutect2, varscan2
- TSC22D1 | c.2843C>A p.A948D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV71775830; called by muse, mutect2, varscan2
- TTN | c.10574C>T p.T3525I (on ENST00000591111; = p.T3479I on NM_003319.4) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV60137387; called by muse, mutect2, varscan2
- UBE2Z | c.1019G>T p.S340I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51726646; called by muse, mutect2, varscan2
- UNC5D | c.1994C>A p.A665E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs781317548, COSV54766380, COSV54783476, COSV54804437; called by muse, mutect2, varscan2
- UPF2 | c.2581C>G p.Q861E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV62660919, COSV62661441; called by muse, mutect2, varscan2
- UQCC1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62902763; called by muse, mutect2, varscan2
- USP6 | c.2062C>G p.Q688E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.361); catalogued as COSV51485370, COSV51496246; called by muse, mutect2, varscan2
- WDR35 | c.1399C>G p.Q467E (on ENST00000345530 / NM_001006657.2; = p.Q456E on NM_020779.4) | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.041); catalogued as rs913648854, COSV55604021, COSV55604700; called by muse, mutect2, varscan2
- WEE1 | c.1740A>T p.L580F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55197547; called by muse, mutect2, varscan2
- WNK4 | c.3495C>A p.S1165R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV55906154; called by muse, mutect2, varscan2
- WRAP73 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54561613; called by muse, mutect2, varscan2
- XIRP1 | c.3380T>A p.L1127Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.248); catalogued as COSV61139167; called by muse, mutect2, varscan2
- XRCC6 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63753077; called by muse, mutect2
- ZBTB10 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs570421287, COSV100990163; called by muse, mutect2, varscan2
- ZFHX4 | c.4198A>G p.N1400D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV51443977; called by muse, mutect2, varscan2
- ZNF554 | c.1173G>C p.R391S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV57886063; called by muse, mutect2, varscan2
- ZNF562 | c.1096C>G p.H366D (on ENST00000453372 / NM_001130032.2; = p.H294D on NM_017656.4) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV53334127, COSV53335694; called by muse, varscan2
- ZNF562 | c.983C>G p.S328* (on ENST00000453372 / NM_001130032.2; = p.S256* on NM_017656.4) | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV53334148; called by muse, varscan2
- CEP70 | c.1231_1248del p.K411_L416del | In Frame Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel*
- CNTNAP5 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CRPPA | c.730del p.A244Pfs*2 (on ENST00000407010 / NM_001368197.1; = p.A194Pfs*2 on NM_001101417.4) | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- IKZF3 | c.543_545del p.Y181_A182delins* | Nonsense Mutation (DEL) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- LEFTY2 | c.183dup p.V62Cfs*191 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- MRC1 | c.298T>C p.W100R | Missense Mutation (SNP) | VAF 161/281 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NF1 | c.4298_4324del p.P1433_M1442delinsL (on ENST00000358273 / NM_001042492.3; = p.P1412_M1421delinsL on NM_000267.3) | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel
- NSUN2 | c.744del p.R248Sfs*4 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- RASL10B | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TRAV21 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUT4 | c.2305_2319del p.M769_S773del | In Frame Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- ABLIM2 | c.849C>A p.I283= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV56406017; called by muse, mutect2, varscan2
- ADAMTS16 | c.516A>T p.R172= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV56993838; called by muse, mutect2, varscan2
- ANKS1B | c.2557T>C p.L853= (on ENST00000547776 / NM_152788.4; = p.L79= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV60366165; called by muse, mutect2
- ARID4B | c.3874T>C p.L1292= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV51605454; called by muse, mutect2
- ART1 | c.96C>G p.L32= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV51705297; called by muse, mutect2, varscan2
- ASXL3 | c.4654T>C p.L1552= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1205406728, COSV52469755; called by muse, mutect2, varscan2
- CARD6 | c.1425C>T p.L475= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV54566899; called by muse, mutect2, varscan2
- CNST | c.1992C>T p.S664= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV63623710; called by muse, mutect2, varscan2
- DIRAS3 | c.660G>A p.E220= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV63970639, COSV63970834; called by muse, mutect2, varscan2
- DUSP14 | c.483C>T p.Y161= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs781030174; called by muse, mutect2, varscan2
- GTF3C1 | c.3972C>T p.V1324= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV62242150; called by muse, mutect2, varscan2
- HECTD4 | c.8724C>T p.L2908= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1301380437, COSV66388399; called by muse, varscan2
- IL17C | c.132C>T p.L44= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs906742659, COSV54918499; called by muse, mutect2, varscan2
- KCNRG | c.396A>G p.T132= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as COSV53950006; called by muse, mutect2, varscan2
- KIF12 | c.1005C>A p.V335= (on ENST00000640217; = p.V197= on NM_138424.1) | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV65117519; called by muse, mutect2, varscan2
- LGR4 | c.2127G>A p.T709= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs750570548, COSV60820977; called by muse, mutect2, varscan2
- LRRC32 | c.123C>G p.L41= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1285173455, COSV52631242; called by muse, mutect2, varscan2
- MPO | c.2127C>T p.I709= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV51859883, COSV51860664; called by muse, mutect2, varscan2
- MSR1 | c.1051C>A p.R351= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV50512381, COSV50515339; called by muse, mutect2
- NDN | c.510G>C p.A170= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV59360208, COSV59362053; called by muse, mutect2, varscan2
- OR1E2 | c.888C>A p.P296= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as COSV50265799; called by muse, mutect2, varscan2
- OR4C16 | c.483C>A p.A161= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV58942557; called by muse, mutect2, varscan2
- OR4C46 | c.450C>T p.G150= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs763740312, COSV60219328, COSV60219955; called by muse, mutect2, varscan2
- OR4K15 | c.282C>T p.D94= (on ENST00000305051; = p.D70= on NM_001005486.1) | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as rs774065100, COSV59300427; called by muse, mutect2, varscan2
- OR5B2 | c.375C>T p.C125= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs747655679, COSV56908624, COSV56908827; called by muse, mutect2, varscan2
- OR8B4 | c.102C>A p.I34= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV62069993; called by muse, mutect2, varscan2
- PIAS2 | c.285C>T p.D95= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV61343779; called by muse, mutect2, varscan2
- PIGS | c.870C>T p.S290= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV52025040; called by muse, varscan2
- PLCB1 | c.1695T>C p.F565= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV62056626; called by muse, mutect2, varscan2
- PLEKHM2 | c.1863C>A p.G621= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV65396751; called by muse, mutect2, varscan2
- RALYL | c.636C>T p.S212= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV72822112; called by muse, mutect2, varscan2
- REG1A | c.90C>A p.P30= | Silent (SNP) | VAF 43/312 reads (14%) | catalogued as COSV99286730; called by muse, mutect2, varscan2
- SEMA4D | c.633C>T p.F211= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs762081174, COSV59396522; called by muse, mutect2, varscan2
- SERINC3 | c.1119C>T p.I373= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV54857302; called by muse, mutect2, varscan2
- SHMT2 | c.660C>G p.L220= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV61074327; called by muse, mutect2, varscan2
- SND1 | c.1494A>G p.E498= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV61243041; called by muse, mutect2, varscan2
- TP53 | c.846G>C p.R282= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53037261, COSV53156241; called by muse, mutect2, varscan2
- TTN | c.71907C>A p.V23969= (on ENST00000591111; = p.V16545= on NM_003319.4) | Silent (SNP) | VAF 55/262 reads (21%) | catalogued as COSV60137343, COSV60162219; called by muse, mutect2, varscan2
- USP48 | c.1083A>G p.P361= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV57611285; called by muse, mutect2, varscan2
- ZNF20 | c.1275T>C p.C425= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV61999702; called by muse, mutect2, varscan2
- ZNF473 | c.2436G>A p.K812= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV54523874; called by muse, mutect2, varscan2
- AGAP2 | chr12:57741972 C>G | 5'Flank (SNP) | VAF 16/100 reads (16%) | catalogued as COSV57729178; called by muse, mutect2, varscan2
- CEP295 | c.5850+145T>C | Intron (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100292201; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+561G>T | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99195160; called by muse, mutect2, varscan2
- UTS2 | chr1:7853419 C>G | 5'Flank (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99276728; called by muse, mutect2, varscan2
- ZNF563 | c.*1A>C | 3'UTR (SNP) | VAF 32/54 reads (59%) | catalogued as COSV99536504; called by muse, mutect2, varscan2
